Somatic mutation profile of tumor specimen MP2PRT-PANXJC-TMP1-A (aliquot MP2PRT-PANXJC-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANXJC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,535 days).
Specimen MP2PRT-PANXJC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83592372-8e13-4066-975e-f8ff0b4bb047.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANXJC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANXJC-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac328d65-e854-4c14-aedc-53e72996db7c

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Ins 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- APOBEC2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 137/369 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs1332743046; called by muse, mutect2, varscan2
- HERC1 | c.14342G>A p.R4781Q | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101496607; called by muse, mutect2
- MROH2B | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 94/275 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs752804955, COSV68185554; called by muse, mutect2, varscan2
- OR56A4 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs749332994; called by muse, mutect2
- OR6T1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as rs374517882, COSV58307745; called by muse, mutect2, varscan2
- SIGLEC1 | c.3769C>T p.R1257W | Missense Mutation (SNP) | VAF 29/332 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs138190270; called by muse, mutect2
- TET3 | c.4079C>T p.A1360V | Missense Mutation (SNP) | VAF 27/451 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as rs748371342; called by muse, mutect2
- TMEM266 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391701952, COSV66379815; called by muse, mutect2
- ZNF174 | c.113dup p.N38Kfs*6 | Frame Shift Ins (INS) | VAF 94/252 reads (37%) | catalogued as rs778043537; called by mutect2, varscan2
- RUNX1T1 | c.1630T>A p.W544R (on ENST00000265814 / NM_001198628.1; = p.W517R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAJ30 | c.1_9delinsGCCCACCCC p.N2_D4delinsPPH | Missense Mutation (ONP) | VAF 11/85 reads (13%) | called by pindel, varscan2*
- ZNF334 | c.579C>T p.N193= | Silent (SNP) | VAF 13/267 reads (5%) | catalogued as rs888062195; called by muse, mutect2
- KDM6B | c.4908+28C>T | Intron (SNP) | VAF 270/576 reads (47%) | catalogued as rs1322259727; called by muse, varscan2
